Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A498, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A498-01A (Primary Tumor).

[page 1 of 5]
Pathology Report

Report Type Pathology Report
Date of Event
Sex F
Authored by
Hosp/Group
Record Status

FINAL DIAGNOSIS:

PART 1: TONGUE, RIGHT MEDIAL, BIOPSY
MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
PART 2: TONGUE, LEFT, PARTIAL GLOSSECTOMY
A. INVASIVE, MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS
CELL
CARCINOMA (4.2 CM).
B. NO ANGIOLYMPHATIC OR PERINEURAL INVASION.
C. ALL FINAL RESECTION MARGINS FREE OF TUMOR (see parts 3-8).
D. PATHOLOGIC STAGE: T3 N0.
PART 3: PHARYNGEAL WALL, LEFT LATERAL, BIOPSY -
NO TUMOR SEEN.
PART 4: FLOOR OF MOUTH, LEFT LATERAL MARGIN, BIOPSY
NO TUMOR PRESENT.
PART 5: DEEP MARGIN, BIOPSY
NO TUMOR PRESENT.
PART 6: ANTERIOR MARGIN, BIOPSY -
NO TUMOR PRESENT.
PART 7: ADDITIONAL MEDIAL TISSUE, BIOPSY -
NO TUMOR PRESENT.
PART 8: FINAL MEDIAL MARGIN, RIGHT, BIOPSY
NO TUMOR PRESENT.
PART 9: LYMPH NODES, LEFT NECK LEVELS 2-4, DISSECTION
TWENTY THREE (23) LYMPH NODES, NO TUMOR PRESENT (0/23).

ICB-0-3

Carcinoma, squamous cell, keratinizing, NOS
8071/3

Site: tongue, NOS CO2.9

hw
9/29/12

My signature is attestation that I have personally reviewed the
submitted
material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

Specimen is received unfixed in nine parts.
Part 1 is labeled with the patient's name, initials XX and "right
medial
tongue". It consists of a 1.8 x 1.4 x 0.8 cm tan-gray, focally
cauterized
soft tissue trisected and evaluated intraoperatively. The remainder of
the
specimen is submitted labeled 1AFS.
Part 2 is labeled with the patient's name, initials XX and "left
partial

[page 2 of 5]
glossectomy, stitch is posterior". It consists of an oriented 6.0 x 2.5 x 2.4 cm partial glossectomy with a roughened red-brown focally cauterized soft tissue margin. Stitch marks posterior. There is a 4.2 x 1.8 x 2.0 cm in depth firm, gray-white and focally hemorrhagic ulcerated lesion surrounded by pink-gray nodular mucosa. The lesion abuts the medial surgical resection margin and comes to within 0.3 cm of the lateral resection margin, 0.3 cm of the anterior resection margin, 1.4 cm of the posterior resection margin and 0.7 cm of the deep surgical resection margin. A representative section of the lesion is evaluated intraoperatively. Digital image is taken. Representative tumor and normal is procured for the head and neck spore tissue bank.

Ink Code:
Red- area of bank tissue

Section code:
2AFS- frozen section, lesion
2B-C- full thickness sections of lesion

Part 3 is labeled with the patient's name, initials XX and "left lateral pharyngeal wall". It consists of a 1.3 x 0.8 x 0.4 cm tan-gray to red focally cauterized soft tissue evaluated intraoperatively. The remainder of the specimen is labeled 3AFS.

Part 4 is labeled with the patient's name, initials XX and "left lateral floor of mouth margin". It consists of a 1.1 x 0.4 x 0.5 cm strip of tan-gray focally cauterized soft tissue evaluated intraoperatively. The remainder of the specimen is submitted labeled 4AFS.

Part 5 is labeled with the patient's name, initials XX and "deep margin". It consists of a 0.6 x 0.4 x 0.3 cm red- gray, focally cauterized soft tissue evaluated intraoperatively. The remainder of the specimen is labeled 5AFS.

Part 6 is labeled with the patient's name, initials XX and "anterior margin". It consists of a 0.5 x 0.4 x 0.3 cm tan-gray, focally cauterized soft tissue evaluated intraoperatively. The remainder of the specimen is submitted labeled 6AFS.

Part 7 is labeled with the patient's name, initials XX and "additional medial tissue". It consists of an unoriented 3.2 x 3.1 x 1.0 cm roughened tan-red hemorrhagic soft tissue bisected and entirely submitted in cassettes labeled 7A & 7B.

[page 3 of 5]
Part 8 is labeled with the patient's name, initials XX and "final medial margin, right". It consists of a 1.9 x 0.7 x 0.4 cm tan-gray, finely granular, soft tissue evaluated intraoperatively. The remainder of the specimen is submitted labeled 8AFS.
Part 9 is labeled with the patient's name, initials XX and "left neck dissection levels II thru IV". It consists of a 12.0 x 2.5 x 0.7 cm portion of soft, yellow-red, focally hemorrhagic and lobular fibroadipose tissue with minimal muscle. The specimen is arbitrarily divided into three portions and on dissection multiple ovoid, soft to moderately firm, tan-pink to red lymph nodes ranging 0.1 cm and 2.5 cm are identified.

Section code:

9A- lymph nodes from 1/3 of specimen at one pole
9B-C- lymph nodes from 1/3 of the specimen, mid aspect
9D-E- lymph nodes from 1/3 of specimen, opposing pole (cassette labeled "9D")

contain one bisected lymph node)

Time in formalin:

GROSSED BY:

INTRAOPERATIVE CONSULTATION:

1AFS: RIGHT MEDIAL TONGUE, (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. MALIGNANT
- C. SQUAMOUS CELL CARCINOMA

2AFS: BIOPSY OF TUMOR (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. MALIGNANT
- C. SQUAMOUS CELL CARCINOMA

3AFS: LEFT LATERAL PHARYNGEAL WALL, SHAVE MARGIN, (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. BENIGN
- C. NO TUMOR SEEN

4AFS: LEFT LATERAL FLOOR MOUTH, SHAVE MARGIN, (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. BENIGN
- C. NO TUMOR SEEN

5AFS: DEEP SHAVE MARGIN, (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. BENIGN
- C. NO TUMOR SEEN

6AFS: ANTERIOR SHAVE MARGIN, (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. BENIGN
- C. NO TUMOR SEEN

8AFS: FINAL MEDIAL MARGIN, RIGHT (frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES
- B. BENIGN
- C. NO TUMOR SEEN

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu

[page 4 of 5]
Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the Department of Pathology, as required by the CLIA

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: left partial glossectomy

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 4.2 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT3

REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 23

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Absent

PERINEURAL INVASION: Absent

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Tongue cancer.

PROCEDURE: Direct laryngoscopy, excision tongue lesion, neck dissection.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Tongue, Medial

Taken:

Stain/ Block

H&E x 1 AFS

Part 2: Tongue, Partial Left

Taken:

[page 5 of 5]
Stain, Block
H&E x 1 B
H&E x 1 C
H&E x 1 AFS
IMSU x 1 (none)
Part 3: Left Lateral Pharyngeal Wall
Taken:
Stain, Block
H&E x 1 AFS
Part 4: Mouth, Floor, Left
Taken:
Stain/ Block
H&E x 1 AFS
H&E x 1 AFS
Part 5: Deep Margins
Taken:
Stain Block
H&E x 1 AFS
Part 6: Anterior Margin
Taken:
Stain Block
H&E x 1 AFS
Part 7: Additional Medial Tissue
Taken:
Stain Block
H&E x 1 A
H&E x 1 B
Part 8: Final Medial Margin. Right
Taken:
Stain/ Block
H&E x 1 AFS
Part 9: Neck Dissection. Left
Taken:
Stain Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
TC1

Source: NCI Genomic Data Commons file 20ebd50b-3dba-47d8-94b0-760d04c42b77 (TCGA-CN-A498.E6F202AD-8C8D-4713-B0E9-BCD08B6E00C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).